Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JE, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JE-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

ICD-6-3
Carcinoma, papillary renal
cell 8260/3
Site: R Kidney NOS C64.9
JW 4/28/14

Final Diagnosis

- A. "SKIN LESION X3 RIGHT FLANK," EXCISION:
Two seborrheic keratosis, both involving inked surgical margin.
One lichenoid keratosis, completely excised.
- B. RIGHT KIDNEY, BIOPSY:
Fibroconnective tissue with atrophic renal tubules and focal mild chronic inflammation,
negative for malignancy.
- C. "RIGHT RENAL MASS," HEMINEPHRECTOMY:
Renal cell carcinoma, papillary type 1, Fuhrman nuclear grade 2 of 4.
Two papillary adenomas, each measuring less than 1 mm.
Portion of adrenal gland with no significant pathological change.
See Key Pathological Findings.
- D. RIGHT ADRENAL GLAND, ADRENALECTOMY:
Adrenal gland with hemorrhage, negative for malignancy.

I, _____ the attending pathologist, personally reviewed the entire case and rendered the final diagnosis. Electronically Signed Out by _____

Key Pathological Findings

Tumor type:	Renal cell carcinoma, papillary type 1.
Nuclear grade:	Fuhrman nuclear grade 2 of 4.
Pattern of growth:	Papillary.
Tumor size:	4 cm.
Invasion through Renal capsule:	Not identified.
Invasion of Gerota's Fascia:	Not applicable.
Renal vein invasion:	Not applicable.
Surgical margins:	Free.
Non-neoplastic kidney:	Focal mild chronic inflammation, glomerulosclerosis, and tubular atrophy.
Adrenal gland:	Not involved.
Lymph nodes:	Not applicable.
Pathologic stage:	pT1aNXMX.

Specimen(s) Received

- A 3 LESIONS RIGHT FLANK - GROSS EXAM
B RENAL BX - RIGHT KIDNEY FS
C RIGHT RENAL MASS FS
D ADRENAL - RIGHT

Clinical History

Right renal mass.

[page 2 of 3]
Preoperative Diagnosis

Mass right kidney.

Intraoperative Consultation

A. SKIN LESION X3 RIGHT FLANK, GROSS EXAMINATION:

Grossly benign.

FSB1. RENAL BIOPSY RIGHT KIDNEY:

Benign fibromuscular tissue with focal inflammation.

No evidence of malignancy.

FSC1. RIGHT RENAL MASS:

Papillary renal cell carcinoma, inked margin is free of tumor.

Comment: These gross and frozen section diagnoses/results were communicated to and acknowledged by

I, _____, have performed the intraoperative consultations and issued the above diagnoses.

Gross Description

A. Specimen A is labeled "skin lesion x3 right flank". The specimen is received fresh and consists of an unoriented, gray-tan, wrinkled ellipse of skin with attached subcutaneous tissue (4.5 x 1) excised to a depth of 1 cm. There are 3 lesions on the epithelium surface ranging from 0.2 cm to 0.6 cm in greatest dimension. The specimen is marked with blue ink on one half and green ink on the opposite half. The remainder of the cut surface is grossly unremarkable. No tissue is submitted to Tissue Procurement Laboratory. Permanent representative sections are submitted as:

A1:	Both tips
A2:	Lesion No. 1 largest
A3:	Lesion No. 2
A4:	Lesion No. 3.

B. The specimen is received fresh for OR consult, labeled "renal biopsy right kidney, frozen section". The specimen consists of a 0.7 x 0.5 x 0.2 cm, soft, red-brown, irregular fragment of tissue which is entirely submitted as frozen section as FSB1.

C. The specimen is received fresh for OR consult, labeled "right renal mass, frozen section margins and diagnosis". The specimen consists of a moderately firm, red-brown, irregular, renal mass which consists of normal renal parenchyma and adipose tissue measuring 6 x 5 x 4.5 cm in overall dimension. The surgical margin of resection is marked with black ink and the renal capsule with adipose tissue is inked blue. Sectioning reveals a soft to somewhat firm yellow-brown, necrotic, partially hemorrhagic mass (4 x 3.5 x 3.3 cm). The mass is located approximately 1.2 cm from the surgical margin of resection. Grossly, the mass does not appear to infiltrate the capsule. The remaining renal parenchyma is grossly unremarkable. Additional sectioning isolates what grossly appears to be a portion of the adrenal gland measuring 2 cm in its greatest dimension. No tissue is submitted to the Tissue Procurement Laboratory. Representative sections are submitted as follows:

FSC1:	Frozen section of renal mass with inked parenchymal margin
-------	--

[page 3 of 3]
(perpendicular section)
C2-C8: Representative section of renal mass
C9: Grossly unremarkable renal parenchyma
C10: Possible adrenal gland
C11: Attached perinephric adipose tissue.

D. Specimen D is labeled "right adrenal". The specimen is received fresh and consists of a 14.1 gm, 7 x 2.5 x 2.5 cm, soft to somewhat firm yellow-tan tissue which is entirely marked with black ink. Serial sections reveal a bright orange peripheral focus with a hemorrhagic center measuring 3.5 x 2 x 1 cm. The remainder of the cut surface is grossly unremarkable. No tissue is submitted to the Tissue Procurement Laboratory. Permanent representative sections are submitted as:

D1-D3: Adrenal gland with a hemorrhagic center
D4: Additional section of adrenal gland.

Source: NCI Genomic Data Commons file c28f94b9-ef1e-447e-b716-8cb7270bf75d (TCGA-2Z-A9JE.D98244DA-ED34-47B3-A5DD-ECED56C07891.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).